Somatic mutation profile of tumor specimen MP2PRT-PANZDA-TMP1-A (aliquot MP2PRT-PANZDA-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANZDA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,686 days).
Specimen MP2PRT-PANZDA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bf404db-0508-4eb7-88b1-ac01c0ea22bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANZDA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANZDA-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac181dc0-c247-4872-8317-4208fef58eaf

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASIC4 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs1358746352, COSV100761842, COSV100761950; called by muse, mutect2, varscan2
- DCAF5 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs764569221; called by muse, mutect2
- HTR1A | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 19/633 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1561279015, COSV60503047; called by muse, mutect2
- PTPRQ | c.6810T>G p.S2270R (on ENST00000616559; = p.S2237R on NM_001145026.2) | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.34); called by muse, mutect2
- RD3 | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 134/509 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- TP53BP1 | c.3951T>A p.S1317R | Missense Mutation (SNP) | VAF 106/366 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- YTHDC1 | c.1216A>T p.S406C (on ENST00000344157 / NM_001031732.4; = p.S388C on NM_133370.4) | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF541 | c.1938C>T p.D646= | Silent (SNP) | VAF 47/459 reads (10%) | catalogued as COSV99644949; called by muse, mutect2, varscan2
- UNC45A | chr15:90934127 G>T | 5'Flank (SNP) | VAF 115/312 reads (37%) | called by muse, mutect2, varscan2
